Somatic mutation profile of tumor specimen 0DSYEF from CCDI case PBCIJE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 13.4 years (4,886 days).
Specimen 0DSYEF: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35607c51-9715-4786-9136-c41b3f9734f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSYE8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d47cbe0a-42c3-469e-93b0-3ff9c19b3eba

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 3'UTR 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADPRM | c.664T>G p.L222V | Missense Mutation (SNP) | VAF 257/745 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- AKAP13 | c.4069G>T p.V1357L | Missense Mutation (SNP) | VAF 62/248 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ILRUN | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 18/447 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.013); called by muse, mutect2
- SAP30L | c.96C>G p.I32M | Missense Mutation (SNP) | VAF 13/464 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.433); called by muse, mutect2
- WDR7 | c.2481G>A p.L827= | Silent (SNP) | VAF 18/514 reads (4%) | called by muse, mutect2
- EPN3 | c.*27C>T | 3'UTR (SNP) | VAF 10/212 reads (5%) | called by muse, mutect2
- TAFA2 | c.*13C>G | 3'UTR (SNP) | VAF 18/634 reads (3%) | catalogued as COSV69173204; called by muse, mutect2
